Somatic mutation profile of tumor specimen 0DJVPN from CCDI case PBBXHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 10.1 years (3,673 days).
Specimen 0DJVPN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a7a7c7a-89a3-4e29-b978-46f01e3b553e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVP9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6487c1e-89a3-40d1-9a20-08e026a01ec8

The open-access MAF lists 3 somatic variants for this specimen: 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJC2 | c.1428-66G>A | Intron (SNP) | VAF 64/192 reads (33%) | catalogued as rs969972261; called by muse, varscan2
- IGFBP3 | c.751-88C>T | Intron (SNP) | VAF 23/62 reads (37%) | catalogued as rs9282735; called by muse, varscan2
- STRAP | c.775+88T>A | Intron (SNP) | VAF 12/83 reads (14%) | called by muse, varscan2
